Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A8C5, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A8C5-01A (Primary Tumor).

[page 1 of 2]
---SURGICAL PATHOLOGY CONSULTATION--- (Accession

Specimen Clinical result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

- A. Soft tissue, small bowel mesentery, excision:
Leiomyosarcoma, 15.3 cm, margins not involved.
- B. Uterus and cervix, hysterectomy:
Leiomyomas.
Endometrial polyps.
Proliferative phase endometrium.
- C. Ovaries and fallopian tubes, left, salpingo-oophorectomy:
Focal ovarian surface adhesions.
- D. Ovary and fallopian tube, right, salpingo-oophorectomy:
No diagnostic abnormality.

Comment:

Date reported:

Pathologist (Electronic Signature)

HISTORY

TISSUE SUBMITTED

- A. Sm bowel mesentery
- B. Uterus, cervix, left tubes + ovaries
- C. Right tube and ovary

FROZEN SECTION

FS:

- A. Small bowel mesentery: FS: Atypical spindle cell lesion with focal necrosis.

GROSS

A. Received fresh in a container labeled with patient's name, hospital number, and "sm bowel mesentery" is a 1110 grams, 15.3 x 12.8 x 10.4 cm pink-tan-yellow, partially encapsulated, firm, nodular mass. The external surface is smooth with no excrescences identified and is intact. The specimen is inked entirely black. The specimen is serially sectioned to reveal tan-pink, trabecular, nodular cut surfaces. No necrosis is grossly identified. A slightly pinker/possibly hemorrhagic nodule is noted grossly abutting the inked surface, 4.0 cm in greatest dimension. Representative sections of the nodule and additional tissue submitted for frozen section, with the remnant in A1. Additional representative sections submitted in A2-A10. Photographs are taken. A portion of tissue is held in for possible cytogenetics.

B. Specimen includes: Received in formalin in a container labeled with the patient's name, hospital number and "Uterus, cervix, left tubes + ovaries" is a hysterectomy and unilateral salpingo-oophorectomy specimen.

Uterine size and weight: 187.85 grams; cornu to cornu, 4.6 cm; cervix to fundus, 8.2 cm; anterior to posterior, 4.0 cm.

Cervix size: 2.5 cm in length x 3.0 cm in diameter with a 0.8 cm slit-like os.

Adnexa measurements: Left fallopian tube, 4.0 cm in length x 0.8 to 2.6 cm in diameter with markedly dilated/edematous fimbriae; left ovary, 1.8 x 1.7 x 1.3 cm and 2.16 grams.

Endometrial thickness in body: 0.15 cm.

Myometrial thickness: 1.6 cm.

Serosal surface abnormalities: The serosal surface is pink-tan, smooth and shiny with four firm subserosal nodules noted, 0.6 to 1.1 cm in greatest dimension. The serosal surface is otherwise grossly unremarkable.

Gross morphologic description: The endometrium is tan-pink, shiny and velvety. Two uterine polyps are noted within fundus of the uterine cavity, 1.2 and 1.9 cm in greatest dimension. The myometrium is tan-pink, smooth and trabeculated. Multiple tan-white, firm, whorled nodules are noted transmurally, 0.3 to 1.7 cm in greatest dimension. The endocervical canal is tan-pink, shiny and herringbone. A 1.0 x 0.5 x 0.2 cm polyp is present within the endocervical canal. The ectocervix is pink-tan, smooth and shiny with focal areas of hemorrhage.

Blocks submitted: B1-B2, lower uterine segment of cervix, anterior; B3-B4, lower uterine segment of cervix, posterior; B5, cervical polyp; B6-B9, full thickness endometrium, anterior, to include entire larger uterine polyps and representative white-tan firm nodule; B10-B11, full thickness endometrium, posterior, to include remaining uterine polyp;

ICD0-3
Leiomyosarcoma NOS
8890/3
Site Metastatic
Mesentery C48.1
JW 11/24/13

[page 2 of 2]
B12, additional representative sections subserosal nodules; B13, ovary; B14, edematous/dilated fimbriae; B15, fallopian tube.

Photograph: None taken.

C. Received in formalin in a container labeled with the patient's name, hospital number and "right tube and ovary" is a 19.5 gram ovary with attached paraovarian tissue and firmly adherent fallopian tube. The ovary is 2.2 x 1.4 x 1.2 cm, tan-pink, shiny and cerebriform. Serial sectioning reveals tan-pink, smooth, fleshy cut surfaces. No masses or lesions are grossly identified. The fallopian tube is purple-red, smooth and shiny with markedly dilated/edematous fimbriae, 5.2 cm in length x 0.4 to 2.2 cm in diameter. Also received free floating in the container is a 1.2 x 3.5 x 0.3 cm aggregate of red-pink, markedly thick mucoid material. Sections submitted as follows: C1, fimbriae perpendicularly; C2, ovary and fallopian tube; C3, representative mucoid material.

MICROSCOPIC

A. Sections reveal a tumor composed of pleomorphic spindle cells variably arranged in a fascicular arrangement. Nuclei show significant pleomorphism. Scattered mitoses are noted. There are foci of necrosis and edema. The tumor is relatively well-circumscribed. Vascular invasion is not noted. Immunoperoxidase studies demonstrate strong staining with vimentin, desmin and S100. There is no significant expression of S100, CD34, CD117 or pankeratin. B, C. Microscopic examination performed and supports the diagnosis.

I have personally reviewed the slides and report for this case.

ADDL PROCEDURES

This test or a subset of these tests was developed and the performance characteristics determined by the
It has not been cleared or approved by the U.S. Food and Drug Administration.

Patient Release Status:

This result is viewable by the patient in

Lab and Collection

--SURGICAL PATHOLOGY CONSULTATION-- (Order

Lab and Collection Information

Result History

--SURGICAL PATHOLOGY CONSULTATION-- (Order

Order Result History Report.

Re

Lab Information

Lab

Style	10/31/13	Yes	No
For Malignancy History			
Just/Synchronous Malignancy Noted			

Source: NCI Genomic Data Commons file 966ee118-4b08-4177-9d13-1409db354d86 (TCGA-X6-A8C5.E4000866-483E-46F4-A27B-9E5B55D4F26F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).